Somatic mutation profile of tumor specimen ALCH-B03Z-TTP1-A (aliquot ALCH-B03Z-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-B03Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.8 years (25,134 days).
Specimen ALCH-B03Z-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b5b7419-7cfa-4776-b870-f83d94ba1269.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B03Z-NB1-A (Blood Derived Normal), aliquot ALCH-B03Z-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93341c6a-e17e-4313-a8d3-4edbf4c3af56

The open-access MAF lists 425 somatic variants for this specimen: 300 protein-altering or splice-affecting, 75 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 75, Intron 26, Nonsense Mutation 20, Splice Site 8, Splice Region 7, RNA 7, 3'UTR 7, Frame Shift Del 6, 5'Flank 5, 5'UTR 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF6 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs121434226, CM044898, HM040054, COSV65419014, COSV65419483; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC011005.1 | c.1109G>C p.R370P | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV101518773; called by muse, mutect2, varscan2
- ADAM29 | c.1333G>C p.D445H | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV100821916; called by muse, mutect2, varscan2
- AFDN | c.2689G>T p.D897Y | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV60046481; called by muse, mutect2, varscan2
- AGBL2 | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV54095931; called by muse, mutect2, varscan2
- ALMS1 | c.12155C>G p.S4052C | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52513505; called by muse, mutect2, varscan2
- AQP1 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV61268567; called by muse, mutect2, varscan2
- BNC1 | c.1899G>C p.E633D | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.339); catalogued as COSV61759301; called by muse, mutect2
- CADM2 | c.1142C>G p.T381R (on ENST00000407528 / NM_001167674.2; = p.T383R on NM_153184.4) | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67378311; called by muse, mutect2, varscan2
- CARD6 | c.713A>T p.H238L | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as COSV54564725; called by muse, mutect2, varscan2
- CASP12 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs995566313; called by muse, mutect2
- CDH18 | c.2180C>A p.P727H | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV56933965; called by muse, mutect2, varscan2
- CFAP94 | c.226G>C p.E76Q (on ENST00000320267 / NM_001352064.2; = p.E82Q on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs760694895; called by muse, mutect2
- CLIC5 | c.1124G>T p.R375L (on ENST00000185206 / NM_001370649.1; = p.R216L on NM_016929.5) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs372300556; called by mutect2, varscan2
- COL1A2 | c.2693G>C p.G898A | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99798199; called by muse, mutect2, varscan2
- CPPED1 | c.881G>C p.S294T | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV55499678; called by muse, mutect2
- CPSF2 | c.1963G>C p.D655H | Missense Mutation (SNP) | VAF 55/523 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.383); catalogued as COSV54097819; called by muse, mutect2, varscan2
- DACH1 | c.2107C>A p.R703S (on ENST00000619232 / NM_001366712.1; = p.R449S on NM_004392.6) | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57498842; called by muse, mutect2, varscan2
- DNAH8 | c.7102G>C p.E2368Q | Missense Mutation (SNP) | VAF 34/680 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as COSV59469692; called by muse, mutect2
- EIF4A2 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 54/536 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV56218989; called by muse, mutect2, varscan2
- EN2 | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52083154; called by muse, mutect2, varscan2
- EPHA3 | c.2424G>T p.W808C | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV60699603; called by muse, mutect2
- FAM135B | c.2760C>G p.N920K | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV52723978, COSV99427814; called by muse, mutect2
- FAM47A | c.656C>A p.P219Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.077); catalogued as rs750698635, COSV60496289; called by muse, mutect2, varscan2
- FBLN2 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs111462798; called by muse, mutect2, varscan2
- FLAD1 | c.803T>G p.M268R | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs138810312; called by muse, mutect2
- FRMD6 | c.995del p.R332Pfs*45 (on ENST00000344768 / NM_001267046.2; = p.R324Pfs*45 on NM_152330.4) | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as COSV61087328; called by mutect2, pindel, varscan2
- FUBP1 | c.1799C>G p.P600R | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.418); catalogued as COSV53935073; called by muse, mutect2
- GALNT17 | c.765-1G>T p.X255_splice | Splice Site (SNP) | VAF 14/76 reads (18%) | catalogued as COSV61199750; called by muse, varscan2
- GALNT17 | c.765G>C p.W255C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99048723; called by muse, mutect2, varscan2
- GFAP | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 13/142 reads (9%) | catalogued as CM136517; called by muse, mutect2
- GIPR | c.855-5C>T | Splice Region (SNP) | VAF 34/256 reads (13%) | catalogued as rs1045126883; called by muse, mutect2, varscan2
- GPX3 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781596538, COSV59305973; called by muse, mutect2, varscan2
- GRIPAP1 | c.1390G>T p.G464W | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV100904329; called by muse, mutect2, varscan2
- GRPR | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1315022179; called by muse, mutect2
- HECW1 | c.3955G>T p.A1319S | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV67823695, COSV67836302; called by muse, mutect2
- HOOK2 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53401724; called by muse, mutect2, varscan2
- IGKV1-8 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 68/341 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs1193785107; called by muse, mutect2, varscan2
- KLHL35 | c.1745G>C p.G582A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.028); catalogued as rs902174152; called by muse, mutect2
- KMT2C | c.6658C>G p.Q2220E | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV51352652; called by muse, mutect2
- LMF1 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753409067, COSV51900422; called by muse, mutect2
- LRRK2 | c.1759G>C p.D587H | Missense Mutation (SNP) | VAF 47/439 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as COSV54150153; called by muse, mutect2, varscan2
- MACF1 | c.3175C>T p.R1059C | Missense Mutation (SNP) | VAF 17/174 reads (10%) | catalogued as rs769675414; called by muse, mutect2, varscan2
- MICAL3 | c.2599del p.T867Pfs*6 | Frame Shift Del (DEL) | VAF 10/95 reads (11%) | catalogued as COSV99261648; called by mutect2, pindel, varscan2
- MIIP | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs571035652; called by muse, mutect2, varscan2
- MUC16 | c.38741C>A p.P12914H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV67477695; called by muse, mutect2
- MUC16 | c.13996C>A p.L4666I | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV67477690; called by muse, mutect2, varscan2
- MUC16 | c.5504T>A p.L1835H | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV67452221; called by muse, mutect2, varscan2
- MXRA5 | c.2777C>A p.T926K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs1018220229; called by muse, mutect2, varscan2
- NCR1 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs369920502; called by muse, mutect2, varscan2
- NSMCE4A | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV64633101; called by muse, mutect2, varscan2
- PADI1 | c.635G>C p.R212T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs1327624028, COSV100969025; called by muse, mutect2, varscan2
- PARP1 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV64692029; called by muse, mutect2, varscan2
- PATL2 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as rs1156483192; called by muse, mutect2
- PCDHB8 | c.2285C>T p.T762M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.684); catalogued as rs557121469; called by muse, mutect2, varscan2
- PITRM1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs752614003, COSV56536213; called by muse, mutect2, varscan2
- POLR3B | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 41/376 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as CM1411464, COSV99943395; called by muse, mutect2, varscan2
- PSAT1 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 53/480 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV61303917; called by muse, mutect2, varscan2
- RASGRP2 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.125); catalogued as COSV62449308; called by muse, mutect2, varscan2
- RHAG | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100006414, COSV57704173; called by muse, mutect2, varscan2
- SENP2 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs772861799; called by muse, mutect2, varscan2
- SIGLEC12 | c.548C>G p.S183C (on ENST00000291707 / NM_053003.4; = p.S65C on NM_033329.2) | Missense Mutation (SNP) | VAF 23/289 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as rs774688289, COSV52460942; called by muse, mutect2
- SLC24A4 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); catalogued as rs773717582; called by muse, mutect2, varscan2
- SLFN12 | c.1288G>C p.V430L | Missense Mutation (SNP) | VAF 32/357 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs778373702; called by muse, mutect2
- SMARCD1 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101202948; called by muse, mutect2, varscan2
- SPANXN3 | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.735); catalogued as COSV65140219; called by muse, mutect2, varscan2
- SPHKAP | c.4217C>T p.S1406F | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.036); catalogued as COSV60874432; called by muse, mutect2
- SPTA1 | c.6679C>A p.L2227M | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs750853080; called by muse, mutect2, varscan2
- SPTLC2 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 33/523 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV53639331; called by muse, mutect2
- SUPT6H | c.3948G>T p.M1316I | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100112226, COSV100112813; called by muse, mutect2
- TAAR2 | c.512C>T p.P171L (on ENST00000367931 / NM_001033080.1; = p.P126L on NM_014626.3) | Missense Mutation (SNP) | VAF 24/311 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414311937; called by muse, mutect2
- TENM2 | c.4180G>A p.D1394N (on ENST00000518659 / NM_001122679.2; = p.D1155N on NM_001080428.3) | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV69127347; called by muse, mutect2, varscan2
- TGFBR3 | c.1669G>T p.G557* | Nonsense Mutation (SNP) | VAF 48/720 reads (7%) | catalogued as COSV53026791; called by muse, mutect2
- THSD7B | c.2025G>T p.E675D | Missense Mutation (SNP) | VAF 59/354 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV55649225; called by muse, mutect2, varscan2
- THSD7B | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 59/355 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55687955; called by muse, mutect2, varscan2
- TNS1 | c.3035G>C p.G1012A | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs201342737; called by muse, mutect2, varscan2
- TRIM48 | c.319C>A p.Q107K | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1194488508; called by muse, mutect2, varscan2
- TRIM71 | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV101070390, COSV101070532; called by muse, mutect2
- TTN | c.92131C>A p.R30711S (on ENST00000591111; = p.R23287S on NM_003319.4) | Missense Mutation (SNP) | VAF 92/452 reads (20%) | PolyPhen probably damaging (0.998); catalogued as COSV59892033, COSV59956068; called by muse, mutect2, varscan2
- UBE2F | c.282G>T p.V94= | Splice Region (SNP) | VAF 8/139 reads (6%) | catalogued as COSV56027727; called by muse, mutect2
- UCP1 | c.500C>A p.T167N | Missense Mutation (SNP) | VAF 81/411 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV99530256; called by muse, mutect2, varscan2
- UGT2B7 | c.1402A>G p.M468V | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs202211253; called by muse, mutect2, varscan2
- UNC79 | c.3220C>G p.L1074V (on ENST00000393151 / NM_001346218.2; = p.L897V on NM_020818.5) | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.651); catalogued as COSV56382854; called by muse, mutect2, varscan2
- USH2A | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 42/642 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs373190681, CM149915, COSV56437947; called by muse, mutect2
- USH2A | c.1613G>T p.C538F | Missense Mutation (SNP) | VAF 60/456 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1513301, COSV56460723; called by muse, mutect2, varscan2
- USP6 | c.1337G>C p.W446S | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV51488117; called by muse, mutect2, varscan2
- VPS13D | c.7056C>G p.S2352R | Missense Mutation (SNP) | VAF 53/340 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.241); catalogued as rs770444197; called by muse, mutect2, varscan2
- VPS13D | c.7057C>T p.P2353S | Missense Mutation (SNP) | VAF 51/340 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs370837150; called by muse, mutect2, varscan2
- VSX1 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1312135864; called by muse, mutect2, varscan2
- XKR4 | c.996G>T p.Q332H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.77); catalogued as rs1190654189, COSV100532548; called by muse, mutect2, varscan2
- XRN1 | c.2231G>C p.G744A | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV53808792; called by muse, mutect2, varscan2
- ZBTB46 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99828611; called by muse, mutect2, varscan2
- ZC3H14 | c.1344G>T p.Q448H | Missense Mutation (SNP) | VAF 36/604 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as rs1177449058, COSV99192950; called by muse, mutect2
- ZNF331 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV53476184, COSV99467801; called by muse, mutect2, varscan2
- ZNF445 | c.104A>C p.Y35S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV68539733; called by muse, mutect2, varscan2
- ZNF507 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1350137058; called by muse, mutect2
- ZNF761 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as rs375418432; called by muse, mutect2, varscan2
- ZNF804B | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV60819221; called by muse, mutect2, varscan2
- ZNF813 | c.1457C>T p.T486M | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs199779555, COSV67177663; called by muse, mutect2, varscan2
- ABI3BP | c.2813G>A p.R938K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- AC013489.1 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACHE | c.204T>G p.F68L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ADAM7 | c.14G>T p.C5F | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFP | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 88/412 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- AGL | c.834T>A p.D278E | Missense Mutation (SNP) | VAF 81/429 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHCTF1 | c.4433C>T p.P1478L (on ENST00000366508; = p.P1452L on NM_015446.5) | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- AKAP17A | c.1152+8G>T | Splice Region (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- ASB10 | c.1143G>T p.E381D (on ENST00000420175 / NM_001142459.2; = p.E366D on NM_080871.4) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ASCC3 | c.1657C>A p.R553S | Missense Mutation (SNP) | VAF 118/434 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ATAD2 | c.2305C>G p.H769D | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATAD2 | c.753A>C p.Q251H | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.325); called by muse, varscan2
- ATF2 | c.1186-1G>T p.X396_splice | Splice Site (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2, varscan2
- ATP12A | c.2443del p.L815Cfs*33 | Frame Shift Del (DEL) | VAF 33/180 reads (18%) | called by mutect2, pindel, varscan2
- ATP6V1A | c.1172G>C p.R391T | Missense Mutation (SNP) | VAF 24/303 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2
- B4GALT5 | c.671A>C p.D224A | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- BAZ1B | c.3032G>T p.G1011V | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BBOF1 | c.758T>A p.L253* | Nonsense Mutation (SNP) | VAF 40/276 reads (14%) | called by muse, mutect2, varscan2
- BCL10 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 62/462 reads (13%) | called by mutect2, varscan2
- BCL2L14 | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- BEGAIN | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BLM | c.1445C>T p.T482I | Missense Mutation (SNP) | VAF 32/423 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.289); called by muse, mutect2
- BMPR2 | c.144G>C p.E48D | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BMT2 | c.658G>C p.D220H | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- BRINP1 | c.236A>T p.K79M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C11orf86 | c.335C>A p.P112Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- C2CD2 | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C4orf54 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- C7 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 47/491 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); called by muse, mutect2
- C8B | c.1621+6T>A | Splice Region (SNP) | VAF 41/313 reads (13%) | called by muse, mutect2, varscan2
- CCDC150 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 72/293 reads (25%) | called by muse, mutect2, varscan2
- CCDC60 | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); called by mutect2, varscan2
- CCNY | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- CDC42BPB | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDHR1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CDKN2AIP | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2
- CEP126 | c.632G>C p.S211T | Missense Mutation (SNP) | VAF 93/387 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CFAP46 | c.3651G>T p.K1217N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP57 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 32/518 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CHD1L | c.1086-6del | Splice Region (DEL) | VAF 39/300 reads (13%) | called by mutect2, pindel, varscan2
- CKAP4 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CKMT2 | c.1015-1G>C p.X339_splice | Splice Site (SNP) | VAF 24/106 reads (23%) | called by muse, varscan2
- CNTN3 | c.514A>T p.R172* | Nonsense Mutation (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- CNTN5 | c.2036T>C p.V679A | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL6A5 | c.1041C>G p.H347Q | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COPA | c.228+4C>A | Splice Region (SNP) | VAF 27/178 reads (15%) | called by muse, mutect2, varscan2
- CPVL | c.1074C>G p.Y358* | Nonsense Mutation (SNP) | VAF 34/355 reads (10%) | called by muse, mutect2, varscan2
- CSMD1 | c.1954C>A p.L652M (on ENST00000520002; = p.L651M on NM_033225.6) | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTSS | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 31/240 reads (13%) | called by muse, mutect2, varscan2
- CUBN | c.10285C>A p.Q3429K | Missense Mutation (SNP) | VAF 72/457 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CYP27C1 | c.603A>T p.E201D | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCHS1 | c.1997del p.K666Sfs*6 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- DDAH1 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 56/397 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH11 | c.2161G>T p.D721Y | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.6688A>T p.T2230S (on ENST00000445597; = p.T2883S on NM_001367479.1) | Missense Mutation (SNP) | VAF 106/459 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DROSHA | c.3317A>T p.K1106I | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- DROSHA | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 17/356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DTHD1 | c.1823A>G p.Y608C (on ENST00000456874; = p.Y443C on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/616 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DYNC2H1 | c.7380G>T p.W2460C | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- EDA2R | c.442G>C p.V148L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EGR1 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- EIF4G3 | c.3266-2A>G p.X1089_splice | Splice Site (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.2607G>T p.W869C (on ENST00000450689 / NM_001142749.3; = p.W702C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ELMOD2 | c.491C>A p.T164K | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPC1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ERO1B | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 24/484 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.141); called by muse, mutect2
- EVC | c.1387A>T p.T463S | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FARP1 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2
- FLG | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- FSCB | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- FUT10 | c.898G>T p.G300W | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAD2 | c.1262T>C p.M421T | Missense Mutation (SNP) | VAF 82/422 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GADD45A | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 47/488 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2
- GET1 | c.452-1G>T p.X151_splice | Splice Site (SNP) | VAF 26/288 reads (9%) | called by muse, mutect2
- GRIK4 | c.2470A>G p.M824V | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM3 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- GUCY1A2 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- H2AC17 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDAC4 | c.2362G>C p.G788R | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- HDC | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 13/340 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- HECW1 | c.2675T>C p.I892T | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- HMX1 | c.763C>A p.R255S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPD | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); called by muse, mutect2
- HOOK1 | c.1583A>G p.Q528R | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- HOXA4 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HS1BP3 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- IFNAR1 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- IGKV1D-43 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- IGKV6D-41 | c.41G>T p.W14L | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- IKBKE | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- INPP1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRX2 | c.1182C>A p.N394K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KAT2A | c.2116G>T p.E706* | Nonsense Mutation (SNP) | VAF 17/112 reads (15%) | called by muse, mutect2, varscan2
- KCNK5 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- KIAA1109 | c.2848del p.E950Sfs*11 | Frame Shift Del (DEL) | VAF 53/371 reads (14%) | called by mutect2, pindel, varscan2
- KIF1B | c.802G>T p.G268* | Nonsense Mutation (SNP) | VAF 49/370 reads (13%) | called by muse, mutect2, varscan2
- KLK3 | c.697C>A p.P233T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- KLK6 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- KRTAP17-1 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 15/93 reads (16%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRIQ3 | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); called by muse, varscan2
- LUM | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- MAGEA11 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- MANEA | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MMP9 | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MORC1 | c.2614A>C p.T872P | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- MRPS10 | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 22/501 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTMR7 | c.17C>A p.T6K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- MUC19 | c.724-1G>C p.X242_splice | Splice Site (SNP) | VAF 22/207 reads (11%) | called by muse, mutect2, varscan2
- MYCBP2 | c.3715A>T p.T1239S (on ENST00000357337; = p.T1277S on NM_015057.5) | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.839); called by mutect2, varscan2
- MYCBP2 | c.3714T>A p.Y1238* (on ENST00000357337; = p.Y1276* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 27/166 reads (16%) | called by muse, mutect2, varscan2
- MYH6 | c.4945C>G p.Q1649E | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- MYO5A | c.1315T>A p.Y439N | Missense Mutation (SNP) | VAF 23/396 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYOC | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 74/298 reads (25%) | called by muse, mutect2, varscan2
- MYOM1 | c.1217A>T p.H406L | Missense Mutation (SNP) | VAF 84/466 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- NCKAP1L | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NCL | c.1985G>T p.G662V | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP13 | c.1629T>G p.F543L | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NSUN6 | c.864G>T p.R288S | Missense Mutation (SNP) | VAF 75/360 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OGDH | c.968G>C p.R323T | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- OPRM1 | c.922G>C p.V308L | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR52E4 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR8D4 | c.105C>A p.Y35* | Nonsense Mutation (SNP) | VAF 35/174 reads (20%) | called by muse, mutect2, varscan2
- OR8S1 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OTUD7B | c.1801A>G p.T601A | Missense Mutation (SNP) | VAF 72/291 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAPOLG | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHA9 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- PCDHGA11 | c.156C>G p.D52E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- PCNX2 | c.4111G>T p.A1371S | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PDCD5 | c.331-1G>C p.X111_splice | Splice Site (SNP) | VAF 29/235 reads (12%) | called by muse, mutect2, varscan2
- PHF21A | c.20A>T p.Q7L | Missense Mutation (SNP) | VAF 14/357 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PIP5K1B | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- PKD1L1 | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PKD1L1 | c.870G>C p.M290I | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKHD1L1 | c.7463C>G p.S2488C | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PKN2 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2
- PLEC | c.9111G>T p.E3037D (on ENST00000322810 / NM_201380.4; = p.E2927D on NM_000445.5) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PLEKHA6 | c.2347G>T p.V783L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHG5 | c.269A>G p.K90R (on ENST00000400915 / NM_001042663.3; = p.K53R on NM_020631.6) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLEKHH1 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- POLR1C | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); called by muse, mutect2
- PPP1R26 | c.3313C>G p.P1105A | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.019); called by muse, varscan2
- PPP1R2B | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 14/431 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); called by muse, mutect2
- PPP2R1A | c.419G>A p.W140* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- PPP4R1 | c.436C>G p.Q146E (on ENST00000400556 / NM_001042388.3; = p.Q129E on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2
- PRDM13 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRICKLE2 | c.488A>G p.Q163R (on ENST00000295902; = p.Q107R on NM_198859.4) | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRMT5 | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRORP | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- RB1 | c.759dup p.R254Qfs*17 | Frame Shift Ins (INS) | VAF 68/413 reads (16%) | called by mutect2, pindel, varscan2
- RBM25 | c.1522G>C p.D508H | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2
- RBM46 | c.1327T>A p.F443I | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- RBM5 | c.409+3G>A | Splice Region (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- RIF1 | c.4302G>C p.K1434N | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- RPAP3 | c.101A>T p.D34V | Missense Mutation (SNP) | VAF 35/397 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- RPLP0 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 29/377 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.234); called by muse, mutect2
- RSPH10B2 | c.638A>G p.K213R | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by mutect2, varscan2
- RXFP3 | c.1072C>G p.P358A | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- RYR2 | c.8011G>C p.A2671P | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SALL3 | c.2834C>A p.P945Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2
- SATB2 | c.836G>A p.S279N | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.159); called by muse, mutect2
- SCN1A | c.2299G>A p.D767N (on ENST00000303395 / NM_001202435.3; = p.D756N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2
- SECISBP2 | c.2519A>T p.E840V | Missense Mutation (SNP) | VAF 159/513 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- SEPTIN4 | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SERPINA4 | c.770A>C p.H257P | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2
- SFRP1 | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHH | c.184T>C p.Y62H | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC22A24 | c.1179A>T p.R393S | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.036); called by muse, mutect2
- SLC25A20 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SP100 | c.2475G>C p.Q825H | Missense Mutation (SNP) | VAF 19/326 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.485); called by muse, mutect2
- SYMPK | c.2357C>T p.T786I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- SYT10 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.067); called by muse, mutect2
- SYT11 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TAF1L | c.2905del p.V969* | Frame Shift Del (DEL) | VAF 22/188 reads (12%) | called by mutect2, pindel, varscan2
- TATDN1 | c.618G>C p.L206F | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- TBC1D15 | c.358A>G p.R120G | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TDRD5 | c.1315A>T p.K439* | Nonsense Mutation (SNP) | VAF 31/170 reads (18%) | called by muse, mutect2, varscan2
- TGFBR3 | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 47/724 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.742); called by muse, mutect2
- TMPRSS6 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 44/209 reads (21%) | called by muse, mutect2, varscan2
- TNN | c.1816G>T p.D606Y | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TP53TG5 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 141/548 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TRANK1 | c.704A>C p.N235T | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRAV9-1 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 18/113 reads (16%) | called by muse, varscan2
- TSPYL6 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UBAP2L | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 22/249 reads (9%) | called by muse, mutect2
- UCHL5 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- UNC13C | c.2112T>A p.D704E | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- USO1 | c.1892C>T p.S631F | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- USP32 | c.740A>G p.H247R | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCAN | c.9097G>A p.V3033M | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- VMO1 | c.419A>T p.N140I | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR33 | c.377G>T p.R126M | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WDR35 | c.2470G>T p.V824L (on ENST00000345530 / NM_001006657.2; = p.V813L on NM_020779.4) | Missense Mutation (SNP) | VAF 159/561 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK2 | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- XG | c.104-2A>T p.X35_splice | Splice Site (SNP) | VAF 20/220 reads (9%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZFPM1 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF207 | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ZNF461 | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 52/519 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- ZNF836 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZSWIM2 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 17/482 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- ZSWIM8 | c.2168G>T p.G723V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ANKFN1 | c.1863T>C p.S621= | Silent (SNP) | VAF 55/336 reads (16%) | called by muse, mutect2, varscan2
- ANKRD62 | c.567T>C p.F189= | Silent (SNP) | VAF 39/428 reads (9%) | called by muse, mutect2
- ARL6IP5 | c.78C>T p.F26= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- ASPM | c.2439G>A p.L813= | Silent (SNP) | VAF 40/704 reads (6%) | called by muse, mutect2
- ATG9B | c.1923G>T p.L641= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- BMPER | c.1647A>T p.T549= | Silent (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- CACNB2 | c.1369C>T p.L457= (on ENST00000324631 / NM_201596.3; = p.L402= on NM_000724.4) | Silent (SNP) | VAF 17/231 reads (7%) | catalogued as COSV56653852, COSV99030389; called by muse, mutect2
- CAMK1 | c.507G>A p.E169= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- CIC | c.1254G>T p.L418= | Silent (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- CPB1 | c.951T>C p.A317= | Silent (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- CRACD | c.1800C>A p.G600= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs367553040, COSV99948699; called by muse, mutect2, varscan2
- DHX35 | c.315G>T p.V105= | Silent (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- DLGAP1 | c.1389G>T p.V463= | Silent (SNP) | VAF 8/33 reads (24%) | called by mutect2, varscan2
- DMAP1 | c.15G>T p.A5= | Silent (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- DMD | c.5616T>A p.A1872= | Silent (SNP) | VAF 69/202 reads (34%) | called by muse, mutect2, varscan2
- DNAH6 | c.456T>A p.T152= | Silent (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2
- FAAP24 | c.459G>A p.L153= | Silent (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- FAM160B1 | c.726C>T p.L242= | Silent (SNP) | VAF 48/218 reads (22%) | catalogued as COSV65088580; called by muse, mutect2, varscan2
- FLT1 | c.1758C>T p.D586= | Silent (SNP) | VAF 68/320 reads (21%) | catalogued as rs753891609, COSV56730259; called by muse, varscan2
- FTHL17 | c.81G>A p.L27= | Silent (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- FZD9 | c.867G>A p.A289= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1275816380; called by muse, mutect2, varscan2
- GARS1 | c.129G>T p.P43= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs1326074084; called by muse, mutect2
- GIMAP8 | c.1761T>G p.L587= | Silent (SNP) | VAF 15/382 reads (4%) | catalogued as COSV56232181; called by muse, mutect2
- GPR42 | c.186G>T p.L62= | Silent (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.1389G>T p.L463= | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- HSD17B3 | c.630G>A p.K210= | Silent (SNP) | VAF 106/309 reads (34%) | catalogued as COSV64557789; called by muse, mutect2, varscan2
- IGHV1-2 | c.57C>G p.S19= | Silent (SNP) | VAF 12/183 reads (7%) | called by muse, mutect2
- ILVBL | c.1869G>T p.T623= | Silent (SNP) | VAF 35/161 reads (22%) | called by muse, mutect2, varscan2
- ITPKB | c.2313G>A p.Q771= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- KIF26A | c.2796G>A p.E932= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- KMT2B | c.7314G>C p.L2438= | Silent (SNP) | VAF 9/193 reads (5%) | called by muse, mutect2
- LAMA1 | c.3315G>A p.E1105= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as rs112855474; called by muse, mutect2, varscan2
- LRRC9 | c.600T>A p.P200= | Silent (SNP) | VAF 43/245 reads (18%) | called by muse, mutect2, varscan2
- MASP1 | c.648C>T p.I216= | Silent (SNP) | VAF 35/262 reads (13%) | catalogued as rs776925228, COSV99397540; called by muse, mutect2, varscan2
- MGAT1 | c.957G>C p.V319= | Silent (SNP) | VAF 24/162 reads (15%) | called by muse, mutect2, varscan2
- MRPL16 | c.69C>G p.L23= | Silent (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- MYCBP2 | c.5970G>T p.P1990= (on ENST00000357337; = p.P2028= on NM_015057.5) | Silent (SNP) | VAF 46/188 reads (24%) | called by muse, mutect2, varscan2
- MYH6 | c.3759G>A p.T1253= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as rs761754298; called by muse, mutect2, varscan2
- NADSYN1 | c.1392G>A p.K464= | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- NFYA | c.606G>A p.Q202= | Silent (SNP) | VAF 14/306 reads (5%) | catalogued as rs1332683674; called by muse, mutect2
- OLIG3 | c.540G>T p.P180= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- OR2T27 | c.39C>A p.I13= | Silent (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- OR8B12 | c.660C>A p.I220= | Silent (SNP) | VAF 35/188 reads (19%) | called by mutect2, varscan2
- PCNX2 | c.4110G>T p.L1370= | Silent (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- PGAP1 | c.1947G>C p.L649= | Silent (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- PHYH | c.735G>T p.R245= | Silent (SNP) | VAF 17/421 reads (4%) | catalogued as COSV53816274; called by muse, mutect2
- PI4KA | c.1125G>T p.L375= | Silent (SNP) | VAF 47/283 reads (17%) | called by muse, mutect2, varscan2
- PLAC8 | c.18G>T p.P6= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs1427527876; called by muse, mutect2, varscan2
- PRAMEF20 | c.981G>A p.L327= | Silent (SNP) | VAF 24/348 reads (7%) | catalogued as rs1048436870; called by muse, mutect2
- PRX | c.2568A>T p.S856= | Silent (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- PTPRO | c.1164G>A p.L388= | Silent (SNP) | VAF 28/306 reads (9%) | catalogued as rs1162623096; called by muse, mutect2
- RAD9A | c.264G>A p.A88= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs781549041, COSV57238266; called by muse, mutect2, varscan2
- RPS15 | c.432C>T p.L144= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as rs200097056; called by muse, mutect2, varscan2
- RSPO3 | c.60C>A p.G20= | Silent (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- RYR2 | c.7020G>T p.G2340= | Silent (SNP) | VAF 58/277 reads (21%) | catalogued as rs767884614, COSV63687686; called by muse, mutect2, varscan2
- SELP | c.138C>T p.Y46= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as COSV55258538; called by muse, mutect2
- SLCO6A1 | c.72C>A p.A24= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV65810707; called by muse, mutect2, varscan2
- SPEM2 | c.633C>A p.G211= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs767957993; called by muse, mutect2, varscan2
- SYNDIG1 | c.348C>A p.I116= | Silent (SNP) | VAF 14/177 reads (8%) | catalogued as COSV100965413; called by muse, mutect2
- TAS1R2 | c.333G>C p.V111= | Silent (SNP) | VAF 28/247 reads (11%) | called by muse, mutect2, varscan2
- TEX15 | c.8172T>C p.N2724= (on ENST00000256246; = p.N3107= on NM_001350162.2) | Silent (SNP) | VAF 43/183 reads (23%) | catalogued as rs771453241; called by muse, mutect2, varscan2
- THOC2 | c.2685A>G p.P895= | Silent (SNP) | VAF 71/213 reads (33%) | called by muse, mutect2, varscan2
- TPK1 | c.723C>T p.I241= | Silent (SNP) | VAF 19/172 reads (11%) | called by muse, mutect2, varscan2
- TRPV6 | c.159C>T p.L53= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- TTN | c.51510T>C p.D17170= (on ENST00000591111; = p.D9746= on NM_003319.4) | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs771353550; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- TTN | c.21732T>C p.Y7244= (on ENST00000591111; = p.Y6317= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/275 reads (21%) | catalogued as rs532700134; called by muse, mutect2, varscan2
- USH2A | c.1614C>T p.C538= | Silent (SNP) | VAF 62/455 reads (14%) | catalogued as rs1195403033; called by muse, mutect2, varscan2
- VPS8 | c.837G>C p.V279= (on ENST00000625842 / NM_001349294.1; = p.V277= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- WFDC10B | c.84G>A p.R28= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV100225083; called by muse, mutect2
- WNT3 | c.36C>A p.L12= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- XAGE5 | c.264G>A p.K88= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs1556777959; called by muse, mutect2, varscan2
- ZFYVE9 | c.3564C>A p.I1188= | Silent (SNP) | VAF 22/453 reads (5%) | called by muse, mutect2
- ZNF618 | c.2277G>T p.L759= (on ENST00000374126 / NM_001318042.2; = p.L666= on NM_133374.2) | Silent (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- ZNF782 | c.1647C>G p.L549= | Silent (SNP) | VAF 20/290 reads (7%) | called by muse, mutect2
- ZNF831 | c.1899G>A p.Q633= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- AC005400.1 | n.179-4742T>A | Intron (SNP) | VAF 32/189 reads (17%) | called by muse, varscan2
- AC027559.1 | n.449A>T | RNA (SNP) | VAF 19/212 reads (9%) | catalogued as rs1451346792; called by muse, mutect2
- AGAP7P | n.333C>A | RNA (SNP) | VAF 21/311 reads (7%) | called by muse, mutect2, varscan2
- ALMS1P1 | n.844G>T | RNA (SNP) | VAF 19/206 reads (9%) | called by muse, mutect2, varscan2
- ANTXRL | c.1045-617G>A | Intron (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2, varscan2
- CARS1 | c.206+320G>T | Intron (SNP) | VAF 31/188 reads (16%) | catalogued as rs1259681725; called by muse, mutect2, varscan2
- CHMP1A | c.7+62G>C | Intron (SNP) | VAF 4/21 reads (19%) | catalogued as rs1038206216; called by muse, mutect2
- CLCA3P | n.665C>T | RNA (SNP) | VAF 16/412 reads (4%) | called by muse, mutect2
- CLPS | chr6:35793526 G>C | 3'Flank (SNP) | VAF 21/410 reads (5%) | called by muse, mutect2
- CSF3R | c.1072-16C>T | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as rs1354082832; called by mutect2, varscan2
- DCTN1 | c.2629-31G>T | Intron (SNP) | VAF 56/259 reads (22%) | called by muse, mutect2, varscan2
- DPT | c.*10A>G | 3'UTR (SNP) | VAF 23/168 reads (14%) | catalogued as rs768106755, COSV100892176; called by muse, mutect2, varscan2
- DYRK2 | c.-65A>G | 5'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs1320584482; called by muse, mutect2, varscan2
- ERCC2 | c.*9G>A | 3'UTR (SNP) | VAF 32/115 reads (28%) | catalogued as rs759571745; called by muse, mutect2, varscan2
- FBXO17 | c.-17-2244G>C | Intron (SNP) | VAF 7/152 reads (5%) | called by muse, mutect2
- FHL1 | c.-242-19A>T | Intron (SNP) | VAF 93/256 reads (36%) | called by muse, mutect2, varscan2
- FOXD4L5 | chr9:65288430 C>T | 5'Flank (SNP) | VAF 16/317 reads (5%) | called by muse, mutect2
- GBA3 | c.59-8420G>T | Intron (SNP) | VAF 47/362 reads (13%) | called by muse, mutect2, varscan2
- GCA | c.*502G>T | 3'UTR (SNP) | VAF 25/157 reads (16%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.2093G>A | RNA (SNP) | VAF 13/239 reads (5%) | catalogued as rs1251702116; called by muse, mutect2
- IGFN1 | c.1242-3217G>A | Intron (SNP) | VAF 28/434 reads (6%) | called by muse, mutect2
- LGALS14 | c.16-646G>C | Intron (SNP) | VAF 19/216 reads (9%) | catalogued as COSV62372504; called by muse, mutect2, varscan2
- MFN2 | c.817-50G>T | Intron (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- MOCOS | c.2165-13C>G | Intron (SNP) | VAF 42/335 reads (13%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12813C>A | Intron (SNP) | VAF 27/228 reads (12%) | called by muse, mutect2, varscan2
- NCSTN | c.86-139C>G | Intron (SNP) | VAF 25/387 reads (6%) | called by muse, mutect2
- NECTIN3-AS1 | n.1172+27C>A | Intron (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- NGDN | c.72+13G>T | Intron (SNP) | VAF 34/166 reads (20%) | called by muse, mutect2, varscan2
- PAXBP1 | c.*7G>C | 3'UTR (SNP) | VAF 51/654 reads (8%) | called by muse, mutect2
- PLEKHA5 | c.1845+3187G>T | Intron (SNP) | VAF 12/125 reads (10%) | called by muse, mutect2
- RBM12B | c.-78+398C>T | Intron (SNP) | VAF 30/218 reads (14%) | called by muse, mutect2, varscan2
- SCAF11 | chr12:45992015 C>A | 5'Flank (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- SCN4B | c.*1926T>C | 3'UTR (SNP) | VAF 10/276 reads (4%) | called by muse, mutect2
- SEPTIN9 | chr17:77281467 C>A | 5'Flank (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- SGCA | c.983+1142C>T | Intron (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- SH3YL1 | c.1+1362C>A | Intron (SNP) | VAF 34/269 reads (13%) | called by muse, mutect2, varscan2
- SLC8A3 | c.2407+45G>C | Intron (SNP) | VAF 52/300 reads (17%) | called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827953 C>T | 3'Flank (SNP) | VAF 9/78 reads (12%) | catalogued as rs373422817, COSV100158028; called by muse, mutect2, varscan2
- SREBF2 | c.1761+603G>T | Intron (SNP) | VAF 12/207 reads (6%) | called by muse, mutect2
- SSPOP | n.2601G>T | RNA (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- TLX1NB | n.1518C>A | RNA (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- TRDN | c.1369+20G>A | Intron (SNP) | VAF 64/195 reads (33%) | catalogued as rs1429384127; called by muse, mutect2, varscan2
- UMPS | c.*2825C>T | 3'UTR (SNP) | VAF 6/84 reads (7%) | catalogued as rs1342211003; called by muse, mutect2
- WDR48 | chr3:39052014 T>C | 5'Flank (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
- Y_RNA | chr12:54102309 C>T | 5'Flank (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- ZNF547 | c.*241G>C | 3'UTR (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- ZNF548 | c.-13G>T | 5'UTR (SNP) | VAF 6/45 reads (13%) | catalogued as rs1323360419; called by muse, mutect2
- ZNF548 | c.-12G>T | 5'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- ZNRD2 | c.19+32G>A | Intron (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- ZSCAN9 | c.569-2116G>A | Intron (SNP) | VAF 64/234 reads (27%) | called by muse, mutect2, varscan2
